Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A4P0, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A4P0-01A (Primary Tumor).

Gross Description: Skin flap of 4 cm in size, with mushroom-like amelanotic formation.

Microscopic Description: Amelanotic melanoma with ulceration, with lymphocytic infiltration. Clark's level IV. Breslow's depth 8 mm.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: Reticular dermis invaded (Clark's level IV), Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, trunk

Tumor size: 0.8 x 0 x 2 cm

Tumor features: Ulcerated

Satellite nodules: Not specified

Histologic type: Amelanotic melanoma

Histologic grade: Poorly differentiated

Lymph nodes: Not specified

Lymphatic invasion: Present

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Tumor Extent: Reticular dermis invaded (Clark's level IV)

Comments: Clark's level IV. Breslow's depth 8 mm.

ICD-0-3

Melanoma, amelanotic 8730/3

Site: Skin, trunk C44.5

10/5/12

Source: NCI Genomic Data Commons file 1a67732f-fc7c-4652-8693-2eaad3742c32 (TCGA-EB-A4P0.3439BA95-7CE8-4F4C-8660-E6FE27108CE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).